HCMI case HCM-CSHL-0808-C55 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/58c8d6cf-e866-4991-b2c0-04f7bf5f71bd

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Days to birth: -27,012 days (74.0 years before the index date); Year of birth: 1947; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C55; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T1b; AJCC pathologic N: N2a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC2; FIGO stage: Stage IIIC2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Peritoneal fluid cytological status: Non-Malignant; Sites of involvement: Lymph node, NOS.
   Pathology details: Lymph node involvement: Positive; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 41 days; Days to treatment end: 146 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 189 days; Days to treatment end: 230 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 0 days.
- Days to follow up: 266 days; Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 156.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.
- MLH1 (IHC): Negative.
- MLH1 hypermethylation: Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- TP53 (IHC): Overexpressed.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Gout; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 55.33 kg; Height: 162.6 cm; BMI: 20.9.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0808-C55-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0808-C55-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0808-C55-01A-01-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
- Sample HCM-CSHL-0808-C55-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0808-C55-11A-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 90; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 7.
- Sample HCM-CSHL-0808-C55-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 14.
